Somatic mutation profile of tumor specimen MP2PRT-PAVNLG-TMP1-A (aliquot MP2PRT-PAVNLG-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVNLG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.6 years (2,419 days).
Specimen MP2PRT-PAVNLG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 438b0dde-5ddc-4714-8325-13fad621a518.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVNLG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVNLG-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b638a732-29cc-4667-90af-4fec31014760

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 30/273 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GAL3ST3 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 23/448 reads (5%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.463); catalogued as COSV61749482; called by muse, mutect2
- USP24 | c.4351C>T p.R1451C | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53766862; called by muse, mutect2
- ARAP3 | c.3152G>T p.C1051F | Missense Mutation (SNP) | VAF 163/342 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CYP4F12 | c.494C>G p.T165R | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IKZF3 | c.1505_1507del p.G502del | In Frame Del (DEL) | VAF 84/204 reads (41%) | called by pindel, varscan2
- PHF6 | c.687dup p.I230Yfs*3 (on ENST00000332070 / NM_032458.3; = p.I231Yfs*3 on NM_032335.3) | Frame Shift Ins (INS) | VAF 12/133 reads (9%) | called by mutect2, pindel, varscan2
- USP9X | c.5694T>G p.Y1898* | Nonsense Mutation (SNP) | VAF 15/186 reads (8%) | called by muse, mutect2
- WDR81 | c.4367C>T p.P1456L (on ENST00000409644 / NM_001163809.2; = p.P405L on NM_152348.4) | Missense Mutation (SNP) | VAF 37/431 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2
- CRB2 | c.2661G>A p.A887= | Silent (SNP) | VAF 165/449 reads (37%) | catalogued as rs1055440896; called by muse, mutect2, varscan2
- FAT1 | c.9456C>T p.A3152= | Silent (SNP) | VAF 24/204 reads (12%) | catalogued as rs539648950; called by muse, mutect2, varscan2
- PCDHGA12 | c.750C>T p.S250= | Silent (SNP) | VAF 22/450 reads (5%) | catalogued as rs774558486, COSV52749810, COSV99337806; called by muse, mutect2
- ABI3BP | c.1576+6250G>A | Intron (SNP) | VAF 73/194 reads (38%) | catalogued as rs572385253, COSV52540172; called by muse, mutect2, varscan2
